FM case AD11281 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/bca0acd2-7552-4273-9983-9c868f413fef

Female, 47.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the rectum; primary biopsied or resected from the rectum. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
